Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28F, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28F-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Sigmoid Distal ☒
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma ☒
Description of other histology:	
Grade:	Moderately Differentiated ☒
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	Lymphoid Aggregates ☒
Crohn's like reaction	☐ None ☒ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☐ No ☒ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	2
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0
Pathologist Comment:	

ICD-O-3

Adenocarcinoma, NOS 8140/3

Site: Sigmoid colon C18-7

for 5/3/11

HPV/MSI Discrepancy		☒
Primary Malignancy History		☒
Local Synchronous Primary Noted		☒

Source: NCI Genomic Data Commons file 46126923-d388-4c3d-b968-2347a619fd56 (TCGA-DM-A28F.E6C435F8-1238-4113-A152-C7AF7620E748.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).